Somatic mutation profile of tumor specimen ALCH-B1W7-TTP1-A (aliquot ALCH-B1W7-TTP1-A-2-0-D-A76I-36) from ALCHEMIST case ALCH-B1W7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.0 years (27,036 days).
Specimen ALCH-B1W7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3ebbbd9-e94f-475c-9880-a2a9a50eb883.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1W7-NB1-A (Blood Derived Normal), aliquot ALCH-B1W7-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b35312bb-d377-41fe-a287-d5f9478e361c

The open-access MAF lists 455 somatic variants for this specimen: 324 protein-altering or splice-affecting, 85 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 284, Silent 85, Intron 19, Nonsense Mutation 19, RNA 17, Splice Site 9, Frame Shift Del 7, 5'UTR 5, Splice Region 4, 5'Flank 2, 3'UTR 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALB | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 36/424 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as rs74821926, CM870084, CM890279, CM910022, COSV55735814; ClinVar: pathogenic; called by muse, mutect2
- F7 | c.681+1G>T p.X227_splice | Splice Site (SNP) | VAF 6/62 reads (10%) | catalogued as rs769452933, CS002133, CS090975; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRT5 | c.1402G>T p.A468S | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1131691471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.518T>A p.V173E | Missense Mutation (SNP) | VAF 16/51 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519747, COSV52679619, COSV52753659, COSV52782945; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB1 | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 71/567 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs754901302; called by muse, mutect2, varscan2
- ABCB1 | c.421G>T p.G141* | Nonsense Mutation (SNP) | VAF 73/575 reads (13%) | catalogued as COSV55950374; called by muse, mutect2, varscan2
- ABHD17B | c.841G>C p.V281L | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100330310; called by muse, mutect2
- ADCYAP1R1 | c.1037G>T p.S346I | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs768498625, COSV100416691; called by muse, mutect2
- ADGB | c.2097C>T p.A699= | Splice Region (SNP) | VAF 20/137 reads (15%) | catalogued as COSV100484206; called by muse, mutect2, varscan2
- AGO1 | c.2254G>T p.A752S | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as COSV64594905; called by muse, varscan2
- AHR | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs757131411, COSV54122212; called by muse, mutect2
- ANP32E | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.511); catalogued as COSV58483354; called by muse, varscan2
- ARHGAP25 | c.658C>T p.R220W (on ENST00000409202 / NM_001007231.3; = p.R212W on NM_014882.3) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs958078986, COSV54900030; called by muse, mutect2, varscan2
- ARID1B | c.5206G>T p.E1736* | Nonsense Mutation (SNP) | VAF 26/288 reads (9%) | catalogued as rs751827621, COSV99034226; called by muse, mutect2
- ASXL3 | c.288A>T p.L96F | Missense Mutation (SNP) | VAF 116/396 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV99325059; called by muse, mutect2, varscan2
- ATP2B2 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749396633, COSV59488346, COSV59493792, COSV59510669; called by muse, mutect2, varscan2
- B3GALT5 | c.714C>A p.Y238* | Nonsense Mutation (SNP) | VAF 8/98 reads (8%) | catalogued as rs771535432; called by muse, mutect2
- BARX2 | c.754C>A p.R252S | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV55651714; called by muse, mutect2
- BNC1 | c.426C>A p.Y142* | Nonsense Mutation (SNP) | VAF 34/148 reads (23%) | catalogued as COSV100597019; called by muse, mutect2
- BPIFC | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.216); catalogued as COSV100300996; called by muse, mutect2, varscan2
- C7 | c.778G>T p.A260S | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV57473921; called by muse, mutect2, varscan2
- CACNA1I | c.4152C>A p.N1384K | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60816885; called by muse, mutect2
- CALCR | c.1054C>T p.H352Y (on ENST00000649521 / NM_001164737.2; = p.H336Y on NM_001742.4) | Missense Mutation (SNP) | VAF 50/271 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs371980647; called by muse, mutect2, varscan2
- CCDC116 | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV53041911; called by muse, mutect2, varscan2
- CCKAR | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99810377; called by muse, mutect2
- CFH | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 36/399 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62778304, COSV99054699; called by muse, mutect2, varscan2
- CILP | c.2187C>A p.F729L | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.316); catalogued as COSV99973747; called by muse, mutect2
- CPXCR1 | c.460C>A p.H154N | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV52161776, COSV52163586; called by muse, mutect2, varscan2
- CR2 | c.2341C>T p.R781* | Nonsense Mutation (SNP) | VAF 19/121 reads (16%) | catalogued as rs766671758, COSV65506850; called by muse, mutect2, varscan2
- CSF2RB | c.2395C>T p.R799C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs544020050, COSV53261337; called by mutect2, varscan2
- CSMD3 | c.9353G>T p.G3118V (on ENST00000297405 / NM_001363185.1; = p.G2949V on NM_052900.3) | Missense Mutation (SNP) | VAF 35/562 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52202347; called by muse, mutect2
- CSMD3 | c.3070C>A p.H1024N (on ENST00000297405 / NM_001363185.1; = p.H920N on NM_052900.3) | Missense Mutation (SNP) | VAF 40/471 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52219274, COSV99847264; called by muse, mutect2
- CSMD3 | c.761G>T p.S254I | Missense Mutation (SNP) | VAF 70/470 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV52138778; called by muse, mutect2, varscan2
- DPYS | c.1284C>A p.F428L | Missense Mutation (SNP) | VAF 37/338 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60907786; called by muse, mutect2, varscan2
- DUOX2 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.153); catalogued as rs781680371; called by muse, mutect2, varscan2
- EEFSEC | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as rs369240402; called by muse, mutect2, varscan2
- ELMO1 | c.1945A>G p.N649D | Missense Mutation (SNP) | VAF 64/279 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1369614587; called by muse, mutect2, varscan2
- ERLIN2 | c.459A>T p.Q153H | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52420389; called by muse, mutect2
- F13B | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1558311941, COSV66374470; called by mutect2, varscan2
- FAM135B | c.3886C>A p.L1296I | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52752535; called by muse, mutect2
- FAM13C | c.150C>A p.D50E | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.182); catalogued as COSV53252101; called by muse, mutect2, varscan2
- FITM1 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV52824319; called by muse, mutect2, varscan2
- FSCB | c.1499C>G p.S500C | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV61216459; called by muse, mutect2, varscan2
- GPR1 | c.350C>G p.A117G | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV67976458; called by muse, mutect2, varscan2
- GTF3C1 | c.5963G>T p.R1988L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV62239601, COSV62245106; called by muse, mutect2, varscan2
- HCLS1 | c.123G>T p.K41N | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100101281; called by muse, mutect2, varscan2
- HTR5A | c.586C>A p.R196S | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs767963101, COSV55281423; called by muse, mutect2, varscan2
- IGF2BP3 | c.979A>G p.I327V | Missense Mutation (SNP) | VAF 158/494 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as rs781122825; called by muse, varscan2
- IPO7 | c.349A>G p.I117V | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.174); catalogued as rs151195385; called by muse, mutect2, varscan2
- JAG1 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as rs1193596340, COSV99652249; called by muse, mutect2
- KLK5 | c.516C>G p.I172M | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV60450018; called by muse, mutect2, varscan2
- KRIT1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 28/387 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV100388632; called by muse, mutect2
- KRTAP6-1 | c.189C>A p.C63* | Nonsense Mutation (SNP) | VAF 47/167 reads (28%) | catalogued as rs142155505; called by muse, mutect2, varscan2
- LGR5 | c.2618G>T p.S873I | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV57004428, COSV57010020; called by muse, mutect2, varscan2
- LILRB2 | c.1712G>T p.R571I | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV58743453, COSV58745032; called by muse, mutect2, varscan2
- LMOD2 | c.842C>A p.T281K | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71755606; called by muse, mutect2, varscan2
- LRRC7 | c.2426G>T p.G809V (on ENST00000651989 / NM_001370785.2; = p.G776V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as COSV99225079, COSV99229611; called by muse, mutect2
- MAGEB6 | c.934G>T p.G312C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV66872016; called by muse, mutect2, varscan2
- MAP2K7 | c.832G>T p.A278S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67609690; called by muse, mutect2, varscan2
- ME3 | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60165117; called by muse, mutect2, varscan2
- MGAM | c.3029A>G p.Y1010C | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1373499992; called by muse, mutect2
- MIA3 | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60514346; called by muse, mutect2
- MSRB3 | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.22); catalogued as rs755325581; called by muse, mutect2, varscan2
- MYH11 | c.4637C>G p.T1546R | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as COSV55556242; called by muse, mutect2
- MYLPF | c.121C>A p.R41S | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100363062; called by muse, mutect2
- NBAS | c.938G>T p.R313L | Missense Mutation (SNP) | VAF 70/448 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV55724549, COSV55729175; called by muse, mutect2, varscan2
- NLRP3 | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as CM068199, COSV60227851; called by muse, mutect2, varscan2
- OR14K1 | c.518A>G p.H173R | Missense Mutation (SNP) | VAF 35/441 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.14); catalogued as COSV51720186, COSV51721281; called by muse, mutect2
- OR14K1 | c.725A>T p.H242L | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767948727; called by muse, mutect2, varscan2
- OR2AK2 | c.66G>T p.W22C | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV63557123, COSV63563546; called by muse, mutect2, varscan2
- OR2F2 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 14/228 reads (6%) | catalogued as rs1210799518; called by muse, mutect2
- OR2T1 | c.425T>C p.M142T | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs770532989; called by muse, mutect2, varscan2
- OR4C3 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60585710; called by muse, mutect2, varscan2
- OR4K5 | c.379T>C p.C127R | Missense Mutation (SNP) | VAF 66/524 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757554825, COSV60003352, COSV60005363; called by muse, mutect2, varscan2
- OTOF | c.2717T>C p.V906A (on ENST00000272371 / NM_194248.3; = p.V159A on NM_004802.4) | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1345614718; called by muse, mutect2, varscan2
- OTOGL | c.4375A>T p.I1459F (on ENST00000547103; = p.I1450F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as rs905383268; called by muse, varscan2
- PAPPA2 | c.4594C>A p.L1532M | Missense Mutation (SNP) | VAF 46/470 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); catalogued as COSV100867637; called by muse, mutect2
- PCYT2 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs867069121; called by muse, mutect2
- PLCB4 | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53795636; called by muse, mutect2, varscan2
- PPP1R3A | c.1020T>A p.N340K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.211); catalogued as COSV52877876; called by muse, mutect2, varscan2
- PRSS16 | c.824T>C p.L275P | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.085); catalogued as rs1270321225; called by muse, mutect2, varscan2
- RIPK1 | c.160A>G p.I54V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs751936916; called by muse, mutect2, varscan2
- RNF6 | c.1398G>T p.R466S | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV60417749; called by muse, mutect2, varscan2
- RTL1 | c.713T>C p.V238A | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.696); catalogued as rs982196981; called by muse, mutect2, varscan2
- SLC5A11 | c.976C>A p.P326T | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV61742336, COSV61743408; called by muse, mutect2, varscan2
- SMAD4 | c.1268G>T p.G423V | Missense Mutation (SNP) | VAF 81/260 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as CD057961; called by muse, mutect2, varscan2
- SPDYE1 | c.736C>A p.R246S | Missense Mutation (SNP) | VAF 85/332 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV51669655, COSV99323960; called by muse, mutect2, varscan2
- SPTA1 | c.6448G>A p.A2150T | Missense Mutation (SNP) | VAF 62/630 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.062); catalogued as COSV63756731, COSV63759956; called by muse, mutect2
- SPTA1 | c.1459C>A p.Q487K | Missense Mutation (SNP) | VAF 46/552 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs562908364; called by muse, mutect2
- ST8SIA5 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 15/129 reads (12%) | PolyPhen possibly damaging (0.721); catalogued as rs1235426885; called by muse, mutect2, varscan2
- SUPT20HL1 | c.2438C>A p.S813* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as rs28689626; called by muse, mutect2, varscan2
- TDRD3 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 15/98 reads (15%) | catalogued as rs1566241835; called by muse, mutect2, varscan2
- TLE1 | c.1062G>T p.A354= | Splice Region (SNP) | VAF 5/52 reads (10%) | catalogued as COSV64691394; called by mutect2, varscan2
- TMEM47 | c.217C>A p.L73I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as rs1473757141; called by muse, mutect2, varscan2
- TMPRSS7 | c.384G>T p.K128N (on ENST00000452346; = p.K16N on NM_001042575.2) | Missense Mutation (SNP) | VAF 50/228 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.875); catalogued as COSV69981953; called by muse, mutect2, varscan2
- TRIML2 | c.558C>A p.S186R | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV100456130; called by muse, mutect2, varscan2
- TRPV6 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as rs376154020; called by muse, mutect2, varscan2
- TTC14 | c.929+1G>T p.X310_splice | Splice Site (SNP) | VAF 16/153 reads (10%) | catalogued as rs1393952331; called by muse, mutect2, varscan2
- TTYH3 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1303764779; called by muse, mutect2, varscan2
- UBE2K | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99787314; called by muse, mutect2
- UBR5 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 95/241 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.198); catalogued as rs1260190339, COSV99642645; called by muse, mutect2, varscan2
- UNC79 | c.5681G>T p.G1894V (on ENST00000393151 / NM_001346218.2; = p.G1717V on NM_020818.5) | Missense Mutation (SNP) | VAF 35/312 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as rs937108046; called by muse, varscan2
- USP15 | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV99739347; called by muse, mutect2, varscan2
- USP29 | c.1594C>A p.P532T | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.714); catalogued as rs1466251128; called by muse, mutect2, varscan2
- USP34 | c.7759A>G p.M2587V | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs1296980453; called by muse, mutect2, varscan2
- WDFY3 | c.3392C>A p.S1131Y | Missense Mutation (SNP) | VAF 50/607 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV55713338, COSV99885949; called by muse, mutect2
- WDR17 | c.487G>T p.V163L | Missense Mutation (SNP) | VAF 48/473 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.472); catalogued as COSV99706612; called by muse, mutect2, varscan2
- XIRP2 | c.9085C>T p.P3029S (on ENST00000628543; = p.P3204S on NM_152381.6) | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV54702368; called by muse, mutect2, varscan2
- ZIC4 | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.194); catalogued as COSV67171328; called by muse, mutect2, varscan2
- ADAMTS16 | c.3051C>A p.N1017K | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.027); called by muse, mutect2
- ADAMTS16 | c.3052C>A p.P1018T | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.939); called by muse, mutect2
- ADGRA1 | c.1400A>G p.H467R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ADGRL2 | c.227C>A p.P76Q | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- AIG1 | c.432G>T p.E144D | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ANP32E | c.321A>C p.E107D | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.118); called by muse, varscan2
- ANP32E | c.320A>G p.E107G | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); called by muse, varscan2
- APBA2 | c.1998C>A p.D666E | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2
- AQP9 | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ASXL3 | c.3281G>T p.G1094V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- ATP1B4 | c.703G>A p.D235N (on ENST00000218008 / NM_001142447.3; = p.D231N on NM_012069.5) | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- B3GALT2 | c.206C>A p.S69* | Nonsense Mutation (SNP) | VAF 76/267 reads (28%) | called by muse, mutect2, varscan2
- BACH2 | c.2452G>A p.V818M | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BMPR1B | c.101G>C p.C34S | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BUB3 | c.320A>T p.E107V | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- C16orf96 | c.2663T>A p.L888Q | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2
- C1orf94 | c.548A>T p.K183M | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- C8B | c.612C>A p.Y204* | Nonsense Mutation (SNP) | VAF 44/389 reads (11%) | called by muse, mutect2, varscan2
- CA5A | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CABS1 | c.494C>A p.T165K | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2
- CACNA1B | c.3554A>T p.Y1185F | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CALCRL | c.379T>A p.C127S | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- CALR | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CAMK2B | c.1145C>A p.T382N | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); called by muse, mutect2
- CARMIL2 | c.326A>T p.Q109L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD93 | c.154C>A p.H52N | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDCP1 | c.745C>G p.L249V | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDH4 | c.502A>G p.K168E | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CENPF | c.866-1G>A p.X289_splice | Splice Site (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- CHD1L | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 36/402 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CHRFAM7A | c.611C>G p.A204G | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CLCN1 | c.1837G>T p.V613L | Missense Mutation (SNP) | VAF 15/316 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); called by muse, mutect2
- CLEC3A | c.511G>T p.G171C (on ENST00000651443; = p.G162C on NM_005752.6) | Missense Mutation (SNP) | VAF 20/237 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CLN3 | c.633G>T p.E211D (on ENST00000360019 / NM_001286104.2; = p.E235D on NM_000086.2) | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNGA3 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2
- CNKSR2 | c.75C>A p.D25E | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- COQ8A | c.622G>T p.V208L | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.416); called by muse, mutect2
- CPSF6 | c.743G>C p.G248A | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CSMD3 | c.3124T>A p.L1042M (on ENST00000297405 / NM_001363185.1; = p.L938M on NM_052900.3) | Missense Mutation (SNP) | VAF 24/454 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSTF2T | c.1498G>T p.G500W | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- CTSD | c.1224G>T p.E408D | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CWF19L2 | c.2189G>T p.W730L | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- CXXC1 | c.1489G>A p.V497I | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- DAOA | c.314T>A p.V105D | Missense Mutation (SNP) | VAF 39/314 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- DDO | c.188C>A p.T63K | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DDX3X | c.1240A>G p.I414V (on ENST00000399959; = p.I415V on NM_001356.5) | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DENND3 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- DGKB | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.059); called by muse, mutect2
- DGKI | c.858T>A p.C286* | Nonsense Mutation (SNP) | VAF 30/196 reads (15%) | called by muse, mutect2, varscan2
- DGKI | c.452T>A p.L151H | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.029); called by muse, mutect2
- DNAJA3 | c.995G>T p.R332M | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- DNASE2B | c.163del p.E55Kfs*7 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | called by mutect2, pindel, varscan2
- DOCK3 | c.526A>T p.S176C | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSEL | c.482G>C p.R161T | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EEFSEC | c.1522G>T p.V508L | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- ENPEP | c.1475G>T p.W492L | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- EPHB2 | c.1889G>A p.G630E (on ENST00000400191 / NM_001309193.2; = p.G631E on NM_004442.7) | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- EVI5 | c.2010G>T p.E670D | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- EXT1 | c.2102G>T p.R701L | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); called by muse, mutect2
- FAM217A | c.1015T>G p.L339V | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM47C | c.3076del p.E1026Kfs*14 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- FCRL5 | c.600G>T p.Q200H | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.814); called by muse, mutect2
- FGL2 | c.295T>C p.C99R | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- FMN2 | c.1760A>T p.Q587L | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- FMO1 | c.416T>C p.I139T | Missense Mutation (SNP) | VAF 80/350 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FMO3 | c.350C>A p.P117H | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FOXRED1 | c.1219T>C p.W407R | Missense Mutation (SNP) | VAF 86/160 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSHR | c.167C>A p.T56N | Missense Mutation (SNP) | VAF 39/463 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.215); called by muse, mutect2
- FSIP2 | c.18733G>A p.D6245N | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- FSTL5 | c.1422G>T p.R474S | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- GABRB1 | c.1322C>A p.P441H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GANAB | c.1999G>A p.G667S | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2
- GAS2L2 | c.1827G>T p.L609F | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- GBP4 | c.320C>T p.T107I | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.119); called by muse, mutect2
- GOLGA8N | c.26A>G p.K9R | Missense Mutation (SNP) | VAF 34/398 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- GPA33 | c.959G>T p.*320Lext*12 | Nonstop Mutation (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2, varscan2
- GPR137C | c.469A>G p.T157A | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIK1 | c.2306A>T p.Q769L | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- HCK | c.250G>T p.V84F | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2
- HDAC9 | c.2823G>T p.M941I | Missense Mutation (SNP) | VAF 52/264 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, varscan2
- HFM1 | c.262C>G p.Q88E | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.16); called by muse, mutect2
- HMCN2 | c.14879C>A p.P4960H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HMGCS2 | c.880G>C p.D294H | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- HTR5A | c.585C>A p.S195R | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- IGKV1-17 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 54/385 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); called by muse, varscan2
- IGLV8-61 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- IGSF9B | c.827T>C p.L276P | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IPO9 | c.3041A>T p.Q1014L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- ITK | c.926A>T p.E309V | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IVNS1ABP | c.473A>T p.Q158L | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IWS1 | c.1873G>T p.D625Y | Missense Mutation (SNP) | VAF 37/276 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KANK1 | c.706G>T p.G236W | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNJ1 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- KCNMA1 | c.1147T>A p.Y383N | Missense Mutation (SNP) | VAF 32/448 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- KCNT2 | c.2414G>C p.S805T | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.235); called by muse, mutect2
- KCNT2 | c.1883G>T p.S628I | Missense Mutation (SNP) | VAF 97/518 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- KIAA2012 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 27/382 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.148); called by muse, mutect2
- KIF12 | c.767G>T p.G256V (on ENST00000640217; = p.G118V on NM_138424.1) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- KMT2B | c.4672G>T p.G1558W | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- KRTAP19-5 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 56/253 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- LRRC63 | c.939C>G p.N313K | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.217); called by muse, varscan2
- LRRC69 | c.535C>G p.Q179E | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- LVRN | c.1891del p.S631Afs*18 | Frame Shift Del (DEL) | VAF 39/166 reads (23%) | called by mutect2, pindel, varscan2
- MALRD1 | c.2157G>T p.K719N | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- MALRD1 | c.2392G>T p.G798C | Missense Mutation (SNP) | VAF 60/260 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- MAP1B | c.4669G>T p.V1557L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MAST2 | c.5209G>A p.E1737K | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2
- MCPH1 | c.238A>T p.R80W | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MDGA2 | c.2658C>A p.S886R (on ENST00000399232 / NM_001113498.2; = p.S588R on NM_182830.4) | Missense Mutation (SNP) | VAF 36/438 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- MEGF10 | c.2266G>C p.A756P | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- MGAM | c.3595C>A p.P1199T | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- MIA3 | c.1669G>T p.E557* | Nonsense Mutation (SNP) | VAF 78/331 reads (24%) | called by muse, mutect2, varscan2
- MPHOSPH6 | c.62G>T p.R21M | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO18B | c.1070A>T p.K357M | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- MYOM3 | c.1924A>G p.T642A | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- NAA11 | c.243C>A p.H81Q | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- NAV3 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- NBAS | c.6148G>T p.G2050C | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NCOA7 | c.323A>T p.Q108L | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- NECAB1 | c.568C>A p.H190N | Missense Mutation (SNP) | VAF 31/380 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- NUDT7 | c.306C>A p.H102Q | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- NXPE2 | c.1312G>A p.V438I | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OBSCN | c.17620_17621del p.A5874* | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by pindel, varscan2
- OPCML | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 28/482 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.065); called by muse, mutect2
- OR10G8 | c.224C>A p.T75K | Missense Mutation (SNP) | VAF 41/365 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- OR10G9 | c.8A>T p.K3M | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.001); called by mutect2, varscan2
- OR10H5 | c.595G>T p.G199C | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- OR10H5 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- OR11G2 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- OR2AK2 | c.65G>T p.W22L | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2T12 | c.81G>A p.M27I | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- OR2T33 | c.344C>A p.A115D | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- OR2W3 | c.780G>T p.M260I | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- OR4A16 | c.201G>T p.M67I | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR4C13 | c.284G>A p.C95Y | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- P4HA3 | c.570G>T p.V190= | Splice Region (SNP) | VAF 37/143 reads (26%) | called by muse, mutect2, varscan2
- PABPC1 | c.1251G>T p.Q417H | Missense Mutation (SNP) | VAF 114/441 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- PABPC4L | c.970G>T p.V324L | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- PCDH18 | c.2920G>T p.A974S | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHGC3 | c.488_497del p.D163Afs*9 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, varscan2
- PDE10A | c.1161C>A p.S387R | Missense Mutation (SNP) | VAF 43/246 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- PDE6B | c.992+1G>T p.X331_splice | Splice Site (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- PHLDB1 | c.3588_3589del p.S1196Rfs*38 | Frame Shift Del (DEL) | VAF 67/166 reads (40%) | called by mutect2, pindel, varscan2
- PHOSPHO1 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PIBF1 | c.1778T>C p.L593P | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- PIF1 | c.1798G>T p.A600S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PLPPR1 | c.242del p.P81Qfs*15 | Frame Shift Del (DEL) | VAF 18/150 reads (12%) | called by mutect2, pindel, varscan2
- POLA1 | c.2629A>G p.T877A | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP2R3A | c.2302A>G p.R768G | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PREX2 | c.3422-1G>T p.X1141_splice | Splice Site (SNP) | VAF 19/134 reads (14%) | called by muse, mutect2, varscan2
- PROM2 | c.1970G>T p.R657L | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- PTN | c.228C>A p.C76* | Nonsense Mutation (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- PTPDC1 | c.1169G>T p.R390L (on ENST00000375360 / NM_177995.3; = p.R442L on NM_152422.4) | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- RAG2 | c.724C>A p.L242M | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM17 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- RECQL5 | c.156G>T p.M52I | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RLBP1 | c.371A>T p.Y124F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- RNF213 | c.1239G>T p.W413C | Missense Mutation (SNP) | VAF 15/209 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ROR1 | c.1199A>G p.N400S | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RSPH10B | c.574-1G>T p.X192_splice | Splice Site (SNP) | VAF 7/55 reads (13%) | called by mutect2, varscan2
- RUNX1T1 | c.1285C>G p.H429D (on ENST00000265814 / NM_001198628.1; = p.H402D on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- SAGE1 | c.2034G>T p.E678D | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SAMSN1 | c.583A>G p.I195V | Missense Mutation (SNP) | VAF 34/300 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- SEPTIN9 | c.317G>C p.R106P (on ENST00000427177 / NM_001113491.2; = p.R88P on NM_006640.4) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SH2B2 | c.1035G>T p.Q345H | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- SIX6 | c.272G>T p.W91L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC8A1 | c.2865G>T p.W955C | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC8A1 | c.2647G>T p.G883C | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLIT2 | c.3592C>A p.L1198M | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.384); called by muse, mutect2
- SPATA3 | c.149G>T p.S50I | Missense Mutation (SNP) | VAF 44/240 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- SPPL3 | c.179G>T p.S60I | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.305); called by muse, varscan2
- STK4 | c.207G>T p.E69D | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- STX1B | c.87G>T p.M29I | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- SZT2 | c.4797G>T p.E1599D (on ENST00000634258 / NM_001365999.1; = p.E1542D on NM_015284.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); called by muse, mutect2
- TAAR6 | c.904T>A p.Y302N | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- TBX18 | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- TDRD15 | c.5539C>A p.P1847T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2
- TECTA | c.238A>T p.S80C | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- TENM2 | c.4108T>A p.Y1370N (on ENST00000518659 / NM_001122679.2; = p.Y1131N on NM_001080428.3) | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TGM5 | c.1940C>A p.S647* (on ENST00000220420 / NM_201631.4; = p.S565* on NM_004245.4) | Nonsense Mutation (SNP) | VAF 91/379 reads (24%) | called by muse, mutect2, varscan2
- THYN1 | c.287A>G p.Y96C | Missense Mutation (SNP) | VAF 11/278 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM132C | c.1361T>A p.I454N | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2
- TMEM144 | c.755T>C p.I252T | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM236 | c.743C>A p.T248K | Missense Mutation (SNP) | VAF 49/425 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM94 | c.2840A>C p.N947T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TMPRSS7 | c.385G>T p.E129* (on ENST00000452346; = p.E17* on NM_001042575.2) | Nonsense Mutation (SNP) | VAF 48/225 reads (21%) | called by muse, mutect2, varscan2
- TP53BP2 | c.1066T>C p.Y356H (on ENST00000343537 / NM_001031685.3; = p.Y227H on NM_005426.2) | Missense Mutation (SNP) | VAF 19/225 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TRBV4-2 | c.97G>T p.G33* | Nonsense Mutation (SNP) | VAF 24/171 reads (14%) | called by muse, mutect2, varscan2
- TRIM77 | c.553A>T p.K185* | Nonsense Mutation (SNP) | VAF 58/229 reads (25%) | called by muse, mutect2, varscan2
- TRPS1 | c.1231G>T p.V411F (on ENST00000220888 / NM_001330599.2; = p.V424F on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- TTC14 | c.929G>T p.C310F | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTC21B | c.1006T>G p.L336V | Missense Mutation (SNP) | VAF 55/299 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- TTN | c.11599A>T p.I3867F (on ENST00000591111; = p.I3821F on NM_003319.4) | Missense Mutation (SNP) | VAF 29/197 reads (15%) | called by muse, mutect2, varscan2
- TXK | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 18/173 reads (10%) | called by muse, mutect2, varscan2
- TYR | c.472C>A p.Q158K | Missense Mutation (SNP) | VAF 180/470 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- UBE2K | c.159A>G p.G53= | Splice Region (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- UNC13A | c.2077A>G p.K693E | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- UNC80 | c.7942G>A p.V2648M | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- USH2A | c.5758G>T p.G1920C | Missense Mutation (SNP) | VAF 34/343 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- USH2A | c.2484A>T p.K828N | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- USP22 | c.743T>C p.V248A | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- USP29 | c.95G>A p.R32K | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- VAV3 | c.2016-2A>T p.X672_splice | Splice Site (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2
- VIP | c.38T>A p.L13Q | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- VMA21 | c.132A>T p.L44F | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VPS13D | c.12662+1G>T p.X4221_splice | Splice Site (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- VWA3A | c.3239G>A p.R1080K | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- VWDE | c.797G>T p.C266F | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- VWF | c.7066C>T p.P2356S | Missense Mutation (SNP) | VAF 69/253 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WDFY4 | c.6605C>A p.S2202Y | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- WDR6 | c.736G>T p.G246C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- ZFHX4 | c.3093+2T>A p.X1031_splice | Splice Site (SNP) | VAF 34/282 reads (12%) | called by muse, mutect2, varscan2
- ZNF395 | c.1471G>T p.G491C | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF444 | c.201G>C p.Q67H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF804B | c.898T>A p.S300T | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ABL2 | c.1998C>T p.P666= (on ENST00000502732 / NM_007314.4; = p.P651= on NM_005158.5) | Silent (SNP) | VAF 54/171 reads (32%) | catalogued as rs138240636; called by muse, mutect2, varscan2
- ACTN2 | c.303C>T p.N101= | Silent (SNP) | VAF 83/288 reads (29%) | catalogued as rs921392642, COSV63977970; called by muse, mutect2, varscan2
- ADARB2 | c.42G>T p.L14= | Silent (SNP) | VAF 17/145 reads (12%) | called by muse, mutect2
- AFF1 | c.576G>A p.S192= | Silent (SNP) | VAF 23/244 reads (9%) | catalogued as rs779004414, COSV57120143; called by muse, mutect2
- AFF2 | c.3306C>A p.A1102= | Silent (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
- ANXA10 | c.199C>T p.L67= | Silent (SNP) | VAF 41/194 reads (21%) | called by muse, mutect2, varscan2
- BTNL9 | c.1404C>T p.G468= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as rs199990647; called by muse, mutect2
- CDH3 | c.2364C>T p.D788= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as rs144637479; ClinVar: uncertain significance; called by muse, mutect2
- CHST4 | c.588C>A p.L196= | Silent (SNP) | VAF 33/123 reads (27%) | called by muse, mutect2, varscan2
- CNTN3 | c.30G>T p.L10= | Silent (SNP) | VAF 20/124 reads (16%) | called by muse, varscan2
- CNTNAP2 | c.1395C>A p.A465= | Silent (SNP) | VAF 35/338 reads (10%) | catalogued as COSV100667136, COSV62267915; called by muse, mutect2
- COL25A1 | c.360C>T p.C120= | Silent (SNP) | VAF 10/176 reads (6%) | catalogued as COSV101211272; called by muse, mutect2
- COL26A1 | c.1251C>T p.P417= (on ENST00000313669 / NM_001278563.3; = p.P415= on NM_133457.4) | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as rs1300390944, COSV58123703; called by muse, mutect2, varscan2
- COL4A2 | c.3570G>A p.P1190= | Silent (SNP) | VAF 40/166 reads (24%) | catalogued as rs774750237, COSV64632151; called by muse, mutect2, varscan2
- CSMD1 | c.9141C>A p.G3047= (on ENST00000520002; = p.G3046= on NM_033225.6) | Silent (SNP) | VAF 29/120 reads (24%) | called by muse, mutect2, varscan2
- CTNND2 | c.2691C>G p.L897= | Silent (SNP) | VAF 33/168 reads (20%) | catalogued as COSV58877132, COSV58898119; called by muse, mutect2, varscan2
- CYLC2 | c.882G>A p.K294= | Silent (SNP) | VAF 18/168 reads (11%) | called by muse, mutect2, varscan2
- DIP2A | c.2325C>T p.V775= | Silent (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- DLG2 | c.963C>T p.P321= | Silent (SNP) | VAF 46/662 reads (7%) | called by muse, mutect2
- DNAAF5 | c.744C>G p.S248= | Silent (SNP) | VAF 11/75 reads (15%) | called by muse, mutect2, varscan2
- EIF4A3 | c.48G>T p.R16= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs376909939; called by mutect2, varscan2
- ERICH3 | c.1359A>T p.S453= | Silent (SNP) | VAF 31/320 reads (10%) | catalogued as COSV100444170; called by muse, mutect2, varscan2
- FAM135B | c.2589T>A p.P863= | Silent (SNP) | VAF 23/394 reads (6%) | called by muse, mutect2
- FAM135B | c.2199A>G p.T733= | Silent (SNP) | VAF 18/165 reads (11%) | called by muse, mutect2, varscan2
- FOXF2 | c.366G>C p.T122= | Silent (SNP) | VAF 21/98 reads (21%) | called by muse, mutect2, varscan2
- FSTL4 | c.2343C>T p.P781= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs775772895, COSV54763886, COSV99532754; called by muse, mutect2, varscan2
- GABRA3 | c.718T>C p.L240= | Silent (SNP) | VAF 8/216 reads (4%) | catalogued as COSV64805366; called by muse, mutect2
- GPR176 | c.978T>C p.S326= | Silent (SNP) | VAF 33/116 reads (28%) | called by muse, mutect2, varscan2
- GREB1L | c.5502C>A p.P1834= | Silent (SNP) | VAF 82/300 reads (27%) | called by muse, mutect2, varscan2
- HAUS6 | c.456A>G p.V152= | Silent (SNP) | VAF 26/244 reads (11%) | catalogued as rs1427112850; called by muse, mutect2
- HCN1 | c.1998G>T p.P666= | Silent (SNP) | VAF 27/294 reads (9%) | catalogued as rs758849997, COSV57528031; called by muse, mutect2
- HMCN1 | c.2829G>T p.G943= | Silent (SNP) | VAF 34/440 reads (8%) | catalogued as COSV54882265; called by muse, mutect2
- IL7R | c.228C>A p.A76= | Silent (SNP) | VAF 74/441 reads (17%) | called by muse, mutect2, varscan2
- INPP4B | c.2658A>T p.I886= | Silent (SNP) | VAF 26/147 reads (18%) | called by muse, mutect2, varscan2
- IQCA1 | c.612G>T p.V204= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV99609700; called by muse, mutect2
- KDM4A | c.3174A>G p.L1058= | Silent (SNP) | VAF 22/93 reads (24%) | called by muse, mutect2, varscan2
- KHDRBS3 | c.354G>C p.A118= | Silent (SNP) | VAF 30/184 reads (16%) | called by muse, varscan2
- KIF21A | c.4152G>T p.G1384= (on ENST00000361418 / NM_001378440.1; = p.G1371= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/342 reads (9%) | called by muse, mutect2
- KIF4A | c.1728A>G p.E576= | Silent (SNP) | VAF 27/122 reads (22%) | catalogued as rs753288132; called by muse, mutect2, varscan2
- KIR3DL3 | c.765A>G p.L255= | Silent (SNP) | VAF 12/123 reads (10%) | called by muse, mutect2, varscan2
- KLRC2 | c.510C>A p.S170= | Silent (SNP) | VAF 36/270 reads (13%) | called by muse, mutect2, varscan2
- KPNA2 | c.753G>A p.Q251= | Silent (SNP) | VAF 38/394 reads (10%) | called by muse, mutect2
- LGALS1 | c.291G>A p.L97= | Silent (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- LOXHD1 | c.6661C>T p.L2221= (on ENST00000642948; = p.L2159= on NM_144612.7) | Silent (SNP) | VAF 51/164 reads (31%) | catalogued as rs1487424468; called by muse, mutect2, varscan2
- LRFN5 | c.1347C>A p.I449= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV104402210; called by muse, mutect2
- MAGI2 | c.1245G>T p.R415= | Silent (SNP) | VAF 17/200 reads (9%) | catalogued as COSV62678141; called by muse, mutect2
- MEOX2 | c.441G>T p.G147= | Silent (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- MIOS | c.369A>G p.P123= | Silent (SNP) | VAF 118/355 reads (33%) | called by muse, mutect2, varscan2
- MUC16 | c.20868C>T p.T6956= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV67474574, COSV67488594; called by muse, mutect2, varscan2
- MUC17 | c.8652T>C p.S2884= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs1562815450; called by muse, mutect2, varscan2
- NFATC1 | c.168G>T p.L56= | Silent (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- NNT | c.450G>T p.T150= | Silent (SNP) | VAF 20/330 reads (6%) | catalogued as rs376583752; called by muse, mutect2
- NRBP2 | c.417G>A p.K139= | Silent (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- NRXN1 | c.3561T>A p.I1187= | Silent (SNP) | VAF 30/148 reads (20%) | called by muse, mutect2, varscan2
- OR11L1 | c.762C>A p.T254= | Silent (SNP) | VAF 20/197 reads (10%) | catalogued as COSV100869502; called by muse, varscan2
- OR13G1 | c.435C>A p.V145= | Silent (SNP) | VAF 90/331 reads (27%) | called by muse, mutect2, varscan2
- OR4K5 | c.726C>A p.S242= | Silent (SNP) | VAF 88/643 reads (14%) | catalogued as COSV100262192, COSV60003827; called by muse, mutect2, varscan2
- PAPPA2 | c.1107C>T p.A369= | Silent (SNP) | VAF 34/95 reads (36%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.1884G>A p.T628= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs772457143, COSV54014030; called by muse, mutect2, varscan2
- PHTF1 | c.720A>G p.P240= | Silent (SNP) | VAF 118/431 reads (27%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.6168T>C p.S2056= | Silent (SNP) | VAF 47/166 reads (28%) | called by muse, mutect2, varscan2
- PRG4 | c.2223C>G p.P741= | Silent (SNP) | VAF 42/192 reads (22%) | called by muse, varscan2
- PRLR | c.1620T>G p.P540= | Silent (SNP) | VAF 51/197 reads (26%) | called by muse, mutect2, varscan2
- RBP3 | c.3504G>A p.G1168= | Silent (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- RGPD3 | c.4824T>A p.S1608= | Silent (SNP) | VAF 15/606 reads (2%) | called by muse, mutect2
- RPIA | c.606G>C p.S202= | Silent (SNP) | VAF 17/204 reads (8%) | called by muse, mutect2
- SERPINB13 | c.433C>A p.R145= | Silent (SNP) | VAF 29/149 reads (19%) | called by muse, varscan2
- SETBP1 | c.4293C>T p.N1431= | Silent (SNP) | VAF 36/310 reads (12%) | called by muse, mutect2, varscan2
- SLC35G4 | c.783C>A p.I261= | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as rs1238697360; called by muse, mutect2, varscan2
- SOHLH2 | c.918A>G p.R306= | Silent (SNP) | VAF 38/181 reads (21%) | called by muse, mutect2, varscan2
- SON | c.2028C>G p.P676= | Silent (SNP) | VAF 10/141 reads (7%) | called by muse, mutect2
- SPANXC | c.216C>A p.A72= | Silent (SNP) | VAF 20/348 reads (6%) | catalogued as COSV62842044; called by muse, mutect2
- SPATA31D1 | c.2202C>A p.I734= | Silent (SNP) | VAF 77/430 reads (18%) | called by muse, mutect2, varscan2
- SPTBN2 | c.7119C>T p.D2373= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as rs1213201129; called by muse, mutect2, varscan2
- STIL | c.511C>T p.L171= | Silent (SNP) | VAF 20/182 reads (11%) | called by muse, mutect2, varscan2
- STYXL2 | c.885T>A p.A295= | Silent (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2
- SUPT20HL2 | c.1449A>G p.Q483= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as rs1458362208; called by muse, mutect2, varscan2
- TRAPPC9 | c.1437C>T p.L479= | Silent (SNP) | VAF 45/449 reads (10%) | called by muse, mutect2, varscan2
- TRPM2 | c.3087C>G p.L1029= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs1366785924; called by muse, mutect2, varscan2
- UGT3A1 | c.123G>T p.R41= | Silent (SNP) | VAF 39/273 reads (14%) | called by muse, mutect2, varscan2
- WDR77 | c.207C>T p.N69= | Silent (SNP) | VAF 11/97 reads (11%) | called by muse, mutect2, varscan2
- YY2 | c.126C>T p.Y42= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as COSV63412856; called by muse, mutect2
- ZNF254 | c.1578C>T p.A526= | Silent (SNP) | VAF 34/308 reads (11%) | called by muse, mutect2
- ZNF530 | c.1506A>G p.R502= | Silent (SNP) | VAF 39/232 reads (17%) | called by muse, mutect2, varscan2
- ZNF697 | c.1443G>C p.T481= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV101360267; called by muse, mutect2, varscan2
- ABCA2 | c.7365+95G>T | Intron (SNP) | VAF 4/38 reads (11%) | called by mutect2, varscan2
- AC114741.1 | n.385G>C | RNA (SNP) | VAF 11/160 reads (7%) | called by muse, mutect2
- AC138749.1 | n.1809G>A | RNA (SNP) | VAF 16/56 reads (29%) | called by mutect2, varscan2
- ACADVL | chr17:7217776 G>A | 5'Flank (SNP) | VAF 28/183 reads (15%) | catalogued as rs1555526671; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS8 | chr11:130401997 G>T | 3'Flank (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- ADH1A | c.828+18C>T | Intron (SNP) | VAF 13/229 reads (6%) | called by muse, mutect2
- AIF1 | c.196+25G>A | Intron (SNP) | VAF 3/20 reads (15%) | catalogued as COSV61962293; called by muse, varscan2
- ASB10 | chr7:151187487 C>A | 5'Flank (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- ATP8B2 | c.130+836G>T | Intron (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- CAPN1 | c.2119-13T>C | Intron (SNP) | VAF 6/67 reads (9%) | called by muse, mutect2
- CASP12 | c.260-465C>A | Intron (SNP) | VAF 101/308 reads (33%) | called by muse, mutect2, varscan2
- CCSER1 | c.2095-12055G>T | Intron (SNP) | VAF 32/283 reads (11%) | catalogued as rs1474647038; called by muse, mutect2, varscan2
- CD46 | c.947-14A>C | Intron (SNP) | VAF 54/179 reads (30%) | called by muse, mutect2, varscan2
- CDRT15P3 | n.524G>T | RNA (SNP) | VAF 6/71 reads (8%) | called by muse, mutect2
- CPT2 | c.-79T>C | 5'UTR (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- DCHS2 | n.4567G>T | RNA (SNP) | VAF 17/159 reads (11%) | called by muse, mutect2, varscan2
- ELOF1 | c.-18-860G>T | Intron (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- FMO9P | n.290A>G | RNA (SNP) | VAF 17/288 reads (6%) | called by muse, mutect2
- GBA3 | c.59-8135A>T | Intron (SNP) | VAF 23/199 reads (12%) | called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.2028G>T | RNA (SNP) | VAF 25/368 reads (7%) | catalogued as rs1554532618; called by muse, mutect2
- HSP90AA4P | n.1745C>A | RNA (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2
- KAT6B | c.1993+51C>T | Intron (SNP) | VAF 26/176 reads (15%) | called by muse, mutect2, varscan2
- KRT8P11 | n.923C>A | RNA (SNP) | VAF 16/162 reads (10%) | catalogued as rs1204169170; called by muse, mutect2
- KRT8P11 | n.1199G>A | RNA (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- MIR1302-4 | n.25G>T | RNA (SNP) | VAF 12/117 reads (10%) | catalogued as rs765089580; called by muse, mutect2, varscan2
- MS4A7 | c.*1088A>T | 3'UTR (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- NADSYN1 | c.798+52G>T | Intron (SNP) | VAF 34/80 reads (43%) | catalogued as rs751704200; called by muse, mutect2, varscan2
- NOC2LP2 | n.1344T>C | RNA (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- NPHS1 | c.-34G>C | 5'UTR (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- OR2W5 | n.870G>T | RNA (SNP) | VAF 17/156 reads (11%) | called by muse, mutect2, varscan2
- PKNOX2 | c.817-57C>A | Intron (SNP) | VAF 101/220 reads (46%) | called by muse, mutect2, varscan2
- PKP4 | c.132+136G>T | Intron (SNP) | VAF 21/250 reads (8%) | called by muse, mutect2
- POFUT2 | c.528-381G>T | Intron (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2
- RHCE | c.149-2551G>T | Intron (SNP) | VAF 28/123 reads (23%) | catalogued as rs1171965724, COSV99604034; called by muse, mutect2, varscan2
- SNORD113-2 | n.29A>T | RNA (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2
- SPATA31C2 | n.2656A>G | RNA (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2, varscan2
- SSPOP | n.10286G>T | RNA (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2, varscan2
- ST14 | c.*31C>T | 3'UTR (SNP) | VAF 15/28 reads (54%) | catalogued as rs765068566, COSV53832905; called by muse, mutect2, varscan2
- TFEC | c.-66G>T | 5'UTR (SNP) | VAF 14/92 reads (15%) | called by muse, mutect2, varscan2
- TMEM183B | n.114C>T | RNA (SNP) | VAF 13/105 reads (12%) | catalogued as rs375958855; called by muse, mutect2, varscan2
- TXNDC8 | c.255+2238C>G | Intron (SNP) | VAF 28/315 reads (9%) | called by muse, mutect2
- UMODL1 | c.1900-41C>A | Intron (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2
- VPS11 | c.-142C>T | 5'UTR (SNP) | VAF 14/357 reads (4%) | called by muse, mutect2
- VWA5B1 | c.710-109G>T | Intron (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- ZFPM2 | n.305C>A | RNA (SNP) | VAF 33/416 reads (8%) | catalogued as rs1485567337; called by muse, mutect2
- ZNF569 | c.-6G>C | 5'UTR (SNP) | VAF 14/101 reads (14%) | called by muse, mutect2, varscan2
